Somatic mutation profile of tumor specimen TCGA-KD-A5QT-01A (aliquot TCGA-KD-A5QT-01A-11D-A27P-09) from TCGA case TCGA-KD-A5QT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 69.1 years (25,249 days).
Specimen TCGA-KD-A5QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38b3a549-3978-4725-9c29-9abf7768ab8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KD-A5QT-10A (Blood Derived Normal), aliquot TCGA-KD-A5QT-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1601006-4e0d-4bbf-a592-63456e15c920

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, In Frame Del 1, Frame Shift Ins 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 18/21 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ALAS2 | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.155); catalogued as COSV100238627; called by muse, mutect2, varscan2
- ATP6AP1 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.114); catalogued as COSV100645203; called by muse, mutect2, varscan2
- DIP2B | c.3781G>T p.G1261C | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99999324; called by muse, mutect2, varscan2
- DNAJB2 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV100339141, COSV60675939; called by muse, mutect2, varscan2
- DOK7 | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100403569; called by muse, mutect2, varscan2
- FAM122B | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99980503; called by muse, mutect2, varscan2
- FKBP4 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1167551753, COSV50009532; called by muse, mutect2, varscan2
- JARID2 | c.1457A>G p.K486R | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100522393; called by muse, mutect2, varscan2
- LIPF | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150812830; called by muse, mutect2, varscan2
- LRP1B | c.10180C>A p.H3394N | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV101260586, COSV67202031; called by muse, mutect2, varscan2
- MORF4L1 | c.703G>T p.D235Y (on ENST00000331268 / NM_206839.2; = p.D196Y on NM_006791.4) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100489213; called by muse, mutect2, varscan2
- MTUS2 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV54985665; called by muse, varscan2
- PPFIBP2 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100206941; called by muse, mutect2, varscan2
- RLIM | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.995); catalogued as COSV100223310; called by muse, mutect2, varscan2
- SRSF4 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs377019095; called by muse, mutect2, varscan2
- SUCNR1 | c.33C>G p.C11W | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100751817, COSV62912648; called by muse, mutect2
- TMTC3 | c.1144A>T p.S382C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99898675; called by muse, mutect2, varscan2
- TRPM5 | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99330522; called by muse, mutect2, varscan2
- TUBGCP3 | c.1973G>A p.S658N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV99997248; called by muse, mutect2, varscan2
- USH2A | c.5731G>A p.G1911R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56409873; called by muse, mutect2, varscan2
- XPNPEP2 | c.1482T>G p.F494L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV100941541; called by muse, mutect2, varscan2
- ZBTB16 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs904248155, COSV60090290; called by muse, mutect2, varscan2
- CHRD | c.440dup p.E148Gfs*6 | Frame Shift Ins (INS) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- TSC2 | c.811_812del p.S271Rfs*66 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- URB2 | c.2993_2995del p.L998del | In Frame Del (DEL) | VAF 30/65 reads (46%) | called by pindel, varscan2
- ZNF488 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARRDC1 | c.336G>A p.R112= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV101004557; called by muse, mutect2, varscan2
- BCAP31 | c.334C>T p.L112= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV100799002; called by muse, mutect2, varscan2
- C1orf210 | c.168C>A p.L56= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV101382237; called by muse, mutect2, varscan2
- DCAF16 | c.576T>C p.T192= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV101200478; called by muse, mutect2, varscan2
- NALCN | c.4551C>T p.Y1517= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs748173874, COSV51929902; called by muse, mutect2, varscan2
- PPFIBP2 | c.1701G>T p.L567= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100206937; called by muse, mutect2, varscan2
- DCHS2 | n.283C>T | RNA (SNP) | VAF 21/42 reads (50%) | catalogued as rs949913153, COSV100253100; called by muse, mutect2, varscan2
